Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A8D0, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A8D0-01A (Primary Tumor).

[page 1 of 2]
Sex: Male
D.O.B.:
MRN #:
Ref Physician:

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Prostate; radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Prostatic adenocarcinoma.
2. Prostate size: 36 grams, 5.7 x 2.9 x 2.9 cm.
3. Tumor quantitation: Tumor occupies 1 to 3% of the prostate gland volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Focally present.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Surgical margins including apex, base, and inked prostatic margin are negative for tumor.

Lymph Node Status:

1. Total number of lymph nodes examined: Ten.
2. Total number of lymph nodes containing metastatic carcinoma: Zero (0/10).

Other:

1. Other significant findings: Perineural invasion present.
2. pTNM stage: pT2aN0.

B. Pelvic lymph node; excision:

No metastatic carcinoma identified in ten lymph nodes (0/10).

ICD O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS 61.9

4/17/14

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Prostate
- B. Pelvic lymph nodes

SPECIMEN DATA

GROSS DESCRIPTION:

A. Received labeled #1 prostate, is a 36 gm prostatectomy specimen, consisting of a 5.7 x 2.9 x 2.9 cm, prostate, with an attached 2.5 x 0.8 x 0.6 cm, left seminal vesicle, a 2.8 x 0.9 x 0.4 cm, right seminal vesicle, a 2.3 x 0.3 cm left vas deferens, and a 2.5 x 0.3 cm, right vas deferens.

The outer surface of the prostate is smooth to shaggy and tan-pink. The cut surface consists of gray-white soft tissue.

The specimen is inked black, serially sectioned, and representative sections are submitted as labeled: 1 - left apical margin (perpendicular); 2 - right apical margin (perpendicular); 3 - left base margin (perpendicular); 4 - right base margin (perpendicular); 5 - left posterior apex; 6 - right posterior apex; 7 - left anterior apex; 8 - right anterior apex; 9 - left posterior mid; 10 - right posterior mid; 11 - left anterior mid; 12 - right anterior mid; 13 - left posterior base; 14 - right posterior base; 15 - left anterior base; 16 - right anterior base; 17 - left vas deferens margin and seminal vesicle junction of prostate; 18 - right vas deferens margin and seminal vesicle. The blocks are labeled.

[page 2 of 2]
INFORMATION

Also received in the same container is a blue, a green, and a yellow cassette, labeled

for genomic research study.

B. Received in formalin labeled , and #2 pelvic lymph nodes, is a 5.9 x 5.4 x 1.5 cm, aggregate of fibroadipose tissue bearing multiple irregular tan-yellow firm tissues consistent with probable lymph node, ranging from 0.2 x 0.2 x 0.1 cm, to 6.2 x 2.1 x 0.7 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety as labeled: 1 -- four whole probable lymph nodes; 2 -- two whole probable lymph nodes; 3 -- one lymph node, bisected; 4-5 -- one lymph node, trisected; 6-8 -- one lymph node, trisected; 9-11 -- one lymph node, trisected; 12-19 -- one lymph node, serially sectioned. The blocks are labeled

Source: NCI Genomic Data Commons file 09182f59-7d5f-4403-a470-bce339ce9e92 (TCGA-HC-A8D0.E29BD9A6-B0F0-42D8-B952-85B71C3D5BC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).